Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3663, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3663-01A (Primary Tumor).

Diagnosis/ diagnoses:

Right hemicolectomy preparation with tumor-free oral and aboral resection margins and a hyperplastic polyp in the ascending colon. It also includes an ulcerated, in parts poorly differentiated adenocarcinoma of the cecum with widespread and deep infiltration of the perimuscular fatty tissue (G3, pT3).

Follow-up report:

Following acetone clarification, 40 lymph nodes in the pericolic fatty tissue bordering the tumor were prepared, measuring up to 1.5 cm.

These proved to be microscopically tumor-free throughout.

In conclusion and in summary a stage of pT3 pN0 (0/40) L0 V0 R0 is established.

Source: NCI Genomic Data Commons file f0d9750d-180d-4f2c-9899-26d05bf43886 (TCGA-AA-3663.3910575F-6B8C-4F8F-9FA2-980D3E848081.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).